Gene-level copy-number profile of tumor specimen ALCH-ABV5-TTP1-A from ALCHEMIST case ALCH-ABV5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.8 years (22,197 days).
Specimen ALCH-ABV5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 053ca684-21c6-4497-aa5c-39dd5ee68904.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABV5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/0231fd1a-b352-4a1d-8ddd-4f6119a58454

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 7,771; copy number 2: 49,398; copy number 3: 737; copy number 4: 128; copy number 5: 45; copy number 6: 41; copy number 7: 81; copy number 8: 70; copy number 9: 11; copy number 11: 79.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:904,834–1,074,306, 19 genes: AL645608.6, AL645608.2, AL645608.4, LINC02593, SAMD11, NOC2L, KLHL17, PLEKHN1, PERM1, AL645608.7, HES4, ISG15, AL645608.3, AL645608.1, AGRN, AL645608.5, AL390719.1, AL645608.8, RNF223.
- chr1:2,425,980–2,526,597, 4 genes: PLCH2, AL139246.1, AL139246.4, PANK4.
- chr2:238,100,340–238,168,900, 4 genes: ESPNL, KLHL30, KLHL30-AS1, ERFE.
- chr4:3,441,968–3,501,473, 2 genes: HGFAC, DOK7.
- chr16:88,382,959–88,440,757, 1 gene: ZNF469.
- chr19:397,589–474,983, 5 genes: AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2.
- chr22:48,538,900–48,547,387, 1 gene (within-gene range 0–2): Z84468.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 327 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,900,493, 70 genes, copy number 8 (broad region; genes not listed).
- chr5:2,184,710–2,262,023, 2 genes, copy number 9: Y_RNA, AC092266.1.
- chr5:4,451,930–6,378,571, 27 genes, copy number 6: AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC010266.2, AC010266.1, AC026797.1, HMGB3P3, LINC02145, MED10.
- chr5:14,581,792–23,689,386, 125 genes, copy number 5–7 (broad region; genes not listed).
- chr12:20,368,537–20,688,583, 1 gene, copy number 5 (within-gene range 2–5): PDE3A.
- chr12:20,551,590–20,916,911, 3 genes, copy number 5 (within-gene range 4–5): AC112777.1, SLCO1C1, SLCO1B3.
- chr12:20,845,065–20,845,260, 1 gene, copy number 5 (within-gene range 4–5): AC011604.1.
- chr12:67,131,567–70,637,440, 80 genes, copy number 6–11 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:46,469,341–46,621,379, 5 genes, copy number 5: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1.
- chr21:10,482,738–13,067,033, 9 genes, copy number 9 (within-gene range 3–9): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 6,302. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
